Somatic mutation profile of tumor specimen MMRF_2572_1_BM_CD138pos (aliquot MMRF_2572_1_BM_CD138pos_T1_KHS5U_L13282) from MMRF case MMRF_2572, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.7 years (27,642 days).
Specimen MMRF_2572_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7daedf80-0262-4572-90da-1abb581e93c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2572_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2572_1_PB_WBC_C3_KHS5U_L13283; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a8ef808-34d8-4086-9f8e-4fb47d7b675a

The open-access MAF lists 133 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 25, Silent 20, Intron 15, 5'UTR 10, 3'Flank 4, Frame Shift Del 3, 5'Flank 3, RNA 2, Nonsense Mutation 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- BDP1 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV62429117; called by muse, mutect2, varscan2
- CAP2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143260592; called by muse, mutect2, varscan2
- CARNS1 | c.2242C>A p.Q748K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs767885917; called by muse, mutect2, varscan2
- DDR2 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1364325806, COSV63373738; called by muse, mutect2
- FBXW10 | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 150/415 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314154880; called by muse, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 52/68 reads (76%) | catalogued as rs754199513; called by mutect2, varscan2
- IGHV1-69 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs11558006; called by muse, mutect2, varscan2
- IGHV2-70 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs769646259; called by muse, varscan2
- IGLV3-1 | c.134A>T p.K45I | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs191755097; called by muse, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, varscan2
- INSYN1 | c.651G>T p.L217F | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.193); catalogued as COSV65837615; called by muse, mutect2
- LOXL1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs745309858; called by muse, mutect2, varscan2
- MTNR1A | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs140222606, COSV56157094; called by muse, mutect2, varscan2
- MUC16 | c.23156C>T p.S7719L | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV67467961; called by muse, mutect2, varscan2
- PTPRF | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs536262487; called by muse, mutect2, varscan2
- SEZ6 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543209673, COSV57985278; called by muse, mutect2, varscan2
- SPAG5 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780067084; called by muse, mutect2, varscan2
- SYT16 | c.105A>T p.L35F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs761390939, COSV101413686; called by muse, mutect2, varscan2
- TSPAN1 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs1227288345; called by muse, mutect2
- AKAP9 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- ANXA1 | c.716A>T p.K239I | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ARHGEF5 | c.3581del p.N1194Tfs*2 | Frame Shift Del (DEL) | VAF 63/622 reads (10%) | called by mutect2, pindel, varscan2
- ARMC2 | c.1597-1G>T p.X533_splice | Splice Site (SNP) | VAF 71/275 reads (26%) | called by muse, varscan2
- ATP2A3 | c.1099T>G p.F367V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- B3GNT5 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2
- BCL7A | c.90A>G p.K30= | Splice Region (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- CBY3 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CFAP46 | c.3532G>C p.D1178H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CNTRL | c.3745G>A p.V1249M | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- COL4A5 | c.3272C>G p.P1091R | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CSMD3 | c.7255A>T p.I2419F (on ENST00000297405 / NM_001363185.1; = p.I2315F on NM_052900.3) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EDNRA | c.689A>C p.E230A | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- EGR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FLRT3 | c.1284A>T p.K428N | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GALNT15 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2
- IGHV2-70 | c.240_242delinsGTA p.Y80_S81delins* | Nonsense Mutation (TNP) | VAF 10/29 reads (34%) | called by pindel, varscan2*
- IGHV2-70 | c.222_224delinsCTT p.W74_D75delinsCF | Missense Mutation (TNP) | VAF 10/26 reads (38%) | called by muse*, pindel, varscan2*
- IGLV3-1 | c.144_145del p.D48Efs*22 | Frame Shift Del (DEL) | VAF 47/101 reads (47%) | called by pindel, varscan2
- KIF21B | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLHDC3 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KRTAP11-1 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LRIG3 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LSAMP | c.153T>A p.H51Q | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MBD3 | c.625A>C p.N209H | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MXRA5 | c.6741C>A p.H2247Q | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OTOG | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PRPF4B | c.2860G>C p.D954H | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRTFDC1 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- RAPGEF2 | c.3944_3947del p.E1315Afs*29 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel
- RUNX1T1 | c.740+5G>T | Splice Region (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- TANC2 | c.1241T>A p.L414Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TBX18 | c.1070T>A p.F357Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF442 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AC126283.2 | c.961T>C p.L321= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs757683052; called by muse, mutect2, varscan2
- AGBL1 | c.2109C>T p.G703= | Silent (SNP) | VAF 46/207 reads (22%) | catalogued as rs770510450, COSV101224419; called by muse, mutect2, varscan2
- ANK2 | c.1398G>A p.T466= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as rs1430075101; called by muse, mutect2
- CORO1A | c.747G>A p.L249= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs772251544; called by muse, mutect2, varscan2
- DSG1 | c.1221T>C p.F407= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as rs769691543; called by muse, mutect2, varscan2
- FGD5 | c.630C>T p.P210= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs769271875; called by muse, mutect2, varscan2
- FZD5 | c.1755G>A p.V585= | Silent (SNP) | VAF 96/176 reads (55%) | called by muse, mutect2, varscan2
- IGHD3-9 | c.3A>G p.V1= | Silent (SNP) | VAF 29/32 reads (91%) | catalogued as rs140560472; called by muse, varscan2
- IGHJ6 | c.61G>C p.*21= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs368258322; called by muse, varscan2
- IGKV2-24 | c.285T>C p.D95= | Silent (SNP) | VAF 79/168 reads (47%) | catalogued as rs749979945; called by muse, mutect2, varscan2
- INHBB | c.663C>G p.L221= | Silent (SNP) | VAF 62/149 reads (42%) | catalogued as COSV54678906; called by muse, mutect2, varscan2
- LMNB1 | c.345C>T p.D115= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- MYCN | c.630C>T p.A210= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- NOVA2 | c.93C>T p.G31= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs376342520; called by muse, mutect2, varscan2
- PDE6B | c.1032T>C p.L344= | Silent (SNP) | VAF 48/197 reads (24%) | called by muse, mutect2, varscan2
- POLE | c.2346C>T p.A782= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs114642756; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBL2 | c.651G>A p.L217= | Silent (SNP) | VAF 54/146 reads (37%) | called by muse, mutect2, varscan2
- TMEM171 | c.354G>C p.L118= | Silent (SNP) | VAF 104/275 reads (38%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.706T>C p.L236= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs867066354; called by muse, mutect2
- UGT1A10 | c.627C>T p.N209= | Silent (SNP) | VAF 88/512 reads (17%) | catalogued as COSV60834152; called by muse, mutect2, varscan2
- AC011294.1 | n.1677G>A | RNA (SNP) | VAF 20/79 reads (25%) | called by mutect2, varscan2
- ACSS3 | c.1354+129C>T | Intron (SNP) | VAF 87/160 reads (54%) | catalogued as COSV54100686; called by muse, mutect2, varscan2
- ALKBH1 | c.*910T>G | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*2773G>T | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38622521 C>G | 5'Flank (SNP) | VAF 66/329 reads (20%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*1729A>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- BCL7A | chr12:122021578 G>C | 5'Flank (SNP) | VAF 43/82 reads (52%) | catalogued as rs570032179, COSV55849579; called by muse, mutect2, varscan2
- C18orf54 | c.*90A>C | 3'UTR (SNP) | VAF 88/291 reads (30%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25456C>T | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- CD300C | c.*80G>A | 3'UTR (SNP) | VAF 51/108 reads (47%) | catalogued as rs796183993, COSV100423295; called by muse, mutect2, varscan2
- CDV3 | c.*350C>T | 3'UTR (SNP) | VAF 47/600 reads (8%) | catalogued as rs749972441; called by muse, mutect2
- CHRNA6 | c.219+76T>C | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- CNST | c.*415T>C | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- CRIM1 | c.*32C>T | 3'UTR (SNP) | VAF 182/486 reads (37%) | catalogued as rs367882463; called by muse, mutect2, varscan2
- CSMD3 | c.7885+157del | Intron (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- CUL3 | c.-283G>A | 5'UTR (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- DLX2 | c.585+249G>A | Intron (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- DMAC1 | chr9:7800148 T>A | 5'Flank (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- ENPP5 | c.*278G>A | 3'UTR (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- FANCI | chr15:89317186 G>A | 3'Flank (SNP) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- FANCI | chr15:89317187 C>A | 3'Flank (SNP) | VAF 8/49 reads (16%) | called by mutect2, varscan2
- FOXI2 | c.*412G>A | 3'UTR (SNP) | VAF 45/92 reads (49%) | catalogued as rs1482360028; called by muse, mutect2, varscan2
- GABRB2 | c.458+127T>C | Intron (SNP) | VAF 17/26 reads (65%) | called by muse, varscan2
- GCC1 | c.*827C>A | 3'UTR (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- GRAMD2A | c.134+377C>T | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as rs570391127; called by muse, mutect2, varscan2
- HS3ST3A1 | c.-682A>G | 5'UTR (SNP) | VAF 47/179 reads (26%) | called by muse, varscan2
- IGHV3-7 | c.-32T>A | 5'UTR (SNP) | VAF 63/147 reads (43%) | catalogued as rs782748556; called by muse, varscan2
- JOSD2 | c.-9G>A | 5'UTR (SNP) | VAF 19/66 reads (29%) | catalogued as rs758221410, COSV100976098; called by muse, mutect2, varscan2
- LSS | c.1989-220T>G | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- MYO3A | c.*6C>A | 3'UTR (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- NPY2R | c.*557G>A | 3'UTR (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100279630; called by muse, mutect2, varscan2
- OTULINL | c.-97G>T | 5'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- PASK | c.3333+817G>A | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- PHLDB3 | chr19:43475090 A>G | 3'Flank (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- PIAS3 | c.804+17C>T | Intron (SNP) | VAF 28/107 reads (26%) | catalogued as rs782153428; called by muse, mutect2, varscan2
- PIWIL4 | c.*406T>C | 3'UTR (SNP) | VAF 42/92 reads (46%) | catalogued as rs1269369896; called by muse, mutect2, varscan2
- PPP2R2B | c.74+20481C>A | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.*2596C>G | 3'UTR (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- PRUNE2 | c.*829T>C | 3'UTR (SNP) | VAF 85/178 reads (48%) | catalogued as rs1424784545; called by muse, mutect2, varscan2
- PTGS2 | c.*1853G>T | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- RPA3 | c.-306A>G | 5'UTR (SNP) | VAF 96/158 reads (61%) | called by muse, varscan2
- RPA3 | c.-448A>G | 5'UTR (SNP) | VAF 55/92 reads (60%) | called by muse, varscan2
- SETBP1 | c.*1523G>T | 3'UTR (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- SGK1 | c.285+1671T>G | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs1337646153; called by muse, mutect2, varscan2
- SLC14A1 | c.*741C>A | 3'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- SLC46A3 | c.*274A>C | 3'UTR (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*3323T>A | 3'UTR (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- SMIM8 | c.*1514T>A | 3'UTR (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- SNX14 | c.-43C>G | 5'UTR (SNP) | VAF 100/148 reads (68%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+49628G>A | Intron (SNP) | VAF 83/189 reads (44%) | catalogued as rs905033211; called by muse, mutect2, varscan2
- TLX1NB | n.1364del | RNA (DEL) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- USP6NL | c.5-4651T>A | Intron (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- WDR90 | c.4311+103G>A | Intron (SNP) | VAF 12/170 reads (7%) | catalogued as rs967425951; called by muse, mutect2
- ZBTB39 | c.*1620G>T | 3'UTR (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-768C>G | 5'UTR (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- ZNF180 | chr19:44473106 C>T | 3'Flank (SNP) | VAF 49/165 reads (30%) | catalogued as rs896008309; called by muse, mutect2, varscan2
- ZNF534 | c.-26G>A | 5'UTR (SNP) | VAF 32/689 reads (5%) | catalogued as rs778110923, COSV99989407; called by muse, mutect2
- ZNF710 | c.*528C>A | 3'UTR (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- ZSCAN12 | c.*566C>T | 3'UTR (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2
